Somatic mutation profile of tumor specimen 0DCWBE from CCDI case PBBLXR, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Rhabdomyosarcoma, NOS; Tissue or organ of origin: Nasopharynx, NOS; Age at diagnosis: 3.3 years (1,205 days).
Specimen 0DCWBE: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e5800acd-af15-41fd-9375-4388bc02e9b6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DCWB3 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/685da832-9e9f-4103-8bc7-398dd6d28734

The open-access MAF lists 17 somatic variants for this specimen: 9 protein-altering or splice-affecting, 2 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 2, 5'UTR 2, 3'UTR 2, Intron 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR4 | c.1648G>C p.V550L | Missense Mutation (SNP) | VAF 817/1128 reads (72%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV52800715, COSV52802492, COSV52804538; called by mutect2, varscan2
- CTNND2 | c.1448C>T p.A483V | Missense Mutation (SNP) | VAF 176/414 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as rs778030487, COSV58867380; called by muse, mutect2, varscan2
- CAMTA1 | c.4357G>T p.A1453S | Missense Mutation (SNP) | VAF 87/246 reads (35%) | SIFT tolerated (0.81); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- COG1 | c.1705A>G p.M569V | Missense Mutation (SNP) | VAF 159/685 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- DEPDC4 | c.577A>T p.N193Y | Missense Mutation (SNP) | VAF 44/669 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2
- FAM71C | c.722T>C p.I241T | Missense Mutation (SNP) | VAF 132/710 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- GLI3 | c.45dup p.V16Sfs*2 | Frame Shift Ins (INS) | VAF 275/756 reads (36%) | called by mutect2, varscan2
- HELB | c.1211A>G p.E404G | Missense Mutation (SNP) | VAF 378/1025 reads (37%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- IWS1 | c.1766C>T p.T589I | Missense Mutation (SNP) | VAF 172/730 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.372); called by muse, varscan2
- C10orf95 | c.634C>T p.L212= | Silent (SNP) | VAF 76/224 reads (34%) | catalogued as rs1176243729; called by muse, mutect2, varscan2
- CPNE4 | c.738C>T p.T246= | Silent (SNP) | VAF 120/358 reads (34%) | called by muse, varscan2
- APBB1IP | c.*61C>A | 3'UTR (SNP) | VAF 4/20 reads (20%) | called by mutect2, varscan2
- C4orf46 | c.-71G>T | 5'UTR (SNP) | VAF 4/30 reads (13%) | called by muse, mutect2, varscan2
- ENO2 | c.181+19del | Intron (DEL) | VAF 74/426 reads (17%) | called by mutect2, varscan2
- GRAMD1B | c.374+4278C>G | Intron (SNP) | VAF 282/1060 reads (27%) | called by muse, mutect2, varscan2
- RMI1 | c.-9T>A | 5'UTR (SNP) | VAF 10/98 reads (10%) | called by muse, varscan2
- UBASH3A | c.*78C>T | 3'UTR (SNP) | VAF 7/18 reads (39%) | called by muse, varscan2
